Surgical pathology report (de-identified scan), TCGA case TCGA-BR-7707, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Asterand, specimen TCGA-BR-7707-01A (Primary Tumor).

[page 1 of 2]
Case ID	Gross Description	Microscopic Description	Diagnosis Details	Comments

[page 2 of 2]
Formatted Path Report

STOMACH TISSUE CHECKLIST

Specimen type: Excision of tumor

Tumor site: Fundus

Tumor size: 6 x 6 x 1 cm

Tumor features: None specified

Histologic type: Adenocarcinoma

Histologic grade: Poorly differentiated

Tumor extent: Muscularis propria

Lymph nodes: 0/2 positive for metastasis (Regional 0/2)

Lymphatic invasion: Not specified

Venous invasion: Not specified

Perineural invasion: Not specified

Margins: Uninvolved

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Not specified

Comments: None

ID	Laterality	Date of procurement
	Fundus	

Source: NCI Genomic Data Commons file c9663262-9602-4029-9c9d-8bdcd23af925 (TCGA-BR-7707.D41C1B15-DF26-46F5-ACCC-289D4B09CAAD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).